Somatic mutation profile of tumor specimen C3L-02136-54 (aliquot CPT0230490001) from CPTAC case C3L-02136, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 54.9 years (20,051 days).
Specimen C3L-02136-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cd27ecd-a9b8-4a3a-bfa6-a7ef5f122016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02136-50 (Buccal Cell Normal), aliquot CPT0230590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e281f65-4020-47a9-8e4f-5df3185b64c9

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 26/176 reads (15%) | catalogued as COSV55457245; called by muse, varscan2
- CACNA2D2 | c.2635A>G p.M879V (on ENST00000479441 / NM_001174051.3; = p.M872V on NM_006030.4) | Missense Mutation (SNP) | VAF 17/566 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ELF4 | c.368_369insCG p.D124Gfs*22 | Frame Shift Ins (INS) | VAF 19/161 reads (12%) | called by pindel, varscan2
- OR2F1 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.167); called by muse, mutect2
- PTPN3 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- SIN3A | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.387); called by muse, mutect2
- TAF5L | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT1 | c.2109C>T p.F703= | Silent (SNP) | VAF 63/383 reads (16%) | called by muse, mutect2, varscan2
